Somatic mutation profile of tumor specimen 0DQZ4C from CCDI case PBCFNL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Malignant tumor, small cell type; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.2 years (2,264 days).
Specimen 0DQZ4C: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 29b413f0-3c54-48a7-96b9-b5078f81aca1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQZ3F (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cfe8de32-0e3d-4aad-baf0-a2873302ba69

The open-access MAF lists 22 somatic variants for this specimen: 12 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 5, 3'Flank 2, 5'UTR 2, Nonsense Mutation 2, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 18/373 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705661, COSV66706270; called by muse, mutect2
- CNGB3 | c.816G>T p.Q272H | Missense Mutation (SNP) | VAF 180/414 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.599); catalogued as COSV60695174; called by mutect2, varscan2
- FMR1 | c.761A>G p.D254G | Missense Mutation (SNP) | VAF 79/516 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- MUC16 | c.8555C>A p.P2852H | Missense Mutation (SNP) | VAF 36/220 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- PCSK2 | c.1691C>A p.A564D | Missense Mutation (SNP) | VAF 46/334 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- PHRF1 | c.1627C>T p.R543* (on ENST00000264555 / NM_001286581.2; = p.R542* on NM_020901.4) | Nonsense Mutation (SNP) | VAF 17/510 reads (3%) | called by muse, mutect2
- SIRT5 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 20/530 reads (4%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.074); called by muse, mutect2
- SSX2IP | c.1371_1377dup p.L460Yfs*11 | Frame Shift Ins (INS) | VAF 66/158 reads (42%) | called by mutect2, varscan2
- TBC1D8B | c.3025G>T p.E1009* | Nonsense Mutation (SNP) | VAF 32/517 reads (6%) | called by muse, mutect2
- UNC80 | c.7153A>G p.T2385A | Missense Mutation (SNP) | VAF 45/363 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- USP17L2 | c.265T>A p.C89S | Missense Mutation (SNP) | VAF 62/1318 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- VWA5A | c.2333C>G p.S778C | Missense Mutation (SNP) | VAF 149/315 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- INVS | c.2391G>A p.E797= | Silent (SNP) | VAF 13/376 reads (3%) | called by muse, mutect2
- NLRP2 | c.645A>C p.A215= | Silent (SNP) | VAF 24/374 reads (6%) | called by muse, mutect2
- RANBP17 | c.3006C>G p.S1002= | Silent (SNP) | VAF 155/337 reads (46%) | called by muse, mutect2, varscan2
- SCARA5 | c.672C>T p.G224= | Silent (SNP) | VAF 232/499 reads (46%) | catalogued as rs1435670479, COSV100107862; called by muse, mutect2, varscan2
- SOX3 | c.852C>A p.P284= | Silent (SNP) | VAF 11/313 reads (4%) | called by muse, mutect2
- HRG | c.639+24T>A | Intron (SNP) | VAF 10/168 reads (6%) | called by muse, mutect2
- JPH2 | c.-71T>C | 5'UTR (SNP) | VAF 18/55 reads (33%) | called by muse, mutect2, varscan2
- MACROH2A1 | chr5:135334128 A>T | 3'Flank (SNP) | VAF 84/205 reads (41%) | called by muse, mutect2, varscan2
- OR6B1 | c.-5C>A | 5'UTR (SNP) | VAF 19/351 reads (5%) | called by muse, mutect2
- TCHHL1 | chr1:152079980 C>T | 3'Flank (SNP) | VAF 51/1178 reads (4%) | catalogued as rs973715135; called by muse, mutect2
